FM case AD13892 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/c776c586-20a4-4123-95bc-a4dbf8ce9700

Female, 33.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Tumor.
